MMRF case MMRF_1030 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4128a4ec-14dc-471b-8836-0edc93ffaf7f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.9 years (24,087 days); ISS stage: I; Days to last known disease status: 1,984 days (5.4 years); Days to last follow up: 1,984 days (5.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 280 days; Days to treatment end: 283 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 283 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 282 days; Days to treatment end: 282 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 284 days; Days to treatment end: 284 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,984 days (5.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 3.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 102 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.3 mg/dL; Immunoglobulin G 41.6 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 55.7 µmol/L; Calcium 2.53 mmol/L; Albumin 37 g/L; Total Protein 9.8 g/dL; Glucose 6.27 mmol/L.
- Day 94 (ECOG 2): M Protein 1.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 219 ×10⁹/L.
- Day 161 (ECOG 0): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.75 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 7.54 mmol/L.
- Day 246 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.478 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.185 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 0.36 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 187 ×10⁹/L.
- Day 346 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.332 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 172 ×10⁹/L.
- Day 449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 7.26 mmol/L.
- Day 561 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.829 mg/dL; Immunoglobulin G 4.99 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L.
- Day 654 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.645 mg/dL; Immunoglobulin G 6 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 1.93 mmol/L; Glucose 6.66 mmol/L.
- Day 743 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.576 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.709 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 15 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 834 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.713 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.73 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 6.99 mmol/L.
- Day 925 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.974 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6.66 mmol/L.
- Day 1,037 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.922 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 8.14 mmol/L.
- Day 1,212 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.811 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.6 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.
- Day 1,478 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.858 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 6.88 mmol/L.
- Day 1,572 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 7.32 mmol/L.
- Day 1,662 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 1.15 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 7.87 mmol/L.
- Day 1,753 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 9.07 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 1.55 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 8.03 mmol/L.
- Day 1,845 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 2.06 g/L; Immunoglobulin M 1.56 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 1,984 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.815 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day -10: Weight: 53 kg; Height: 147 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1030_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1030_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
